Somatic mutation profile of tumor specimen 51c1c79e-5a8e-4b0a-bf92-1c0cab (aliquot 51c1c79e-5a8e-4b0a-bf92-1c0cab_D6) from CPTAC case 11OV009, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC.
Specimen 51c1c79e-5a8e-4b0a-bf92-1c0cab: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 544135ed-a179-409c-b0d5-adb4fe451125.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 30bf6cbf-c613-4128-86f5-de7bf0 (Blood Derived Normal), aliquot 30bf6cbf-c613-4128-86f5-de7bf0_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f3f5528-7562-445b-9adf-c668f6c77966

The open-access MAF lists 89 somatic variants for this specimen: 64 protein-altering or splice-affecting, 10 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 10, 5'UTR 5, Intron 4, 3'UTR 4, Splice Site 3, In Frame Del 2, 5'Flank 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP23 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs557284890; called by muse, mutect2, varscan2
- BRCA2 | c.5111G>A p.R1704K | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99061612; called by muse, mutect2, varscan2
- COL4A4 | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 41/615 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.406); catalogued as COSV61633711; called by muse, mutect2
- CTTNBP2 | c.2206G>C p.D736H | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50485634; called by muse, mutect2
- DNAJC6 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54781712; called by muse, mutect2, varscan2
- EIF4G1 | c.3551G>A p.R1184Q (on ENST00000346169 / NM_198241.3; = p.R989Q on NM_004953.5) | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs756664955, COSV59988982; called by muse, mutect2, varscan2
- EXD3 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as rs201064460; called by muse, varscan2
- FLRT2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs375582864, COSV58146183; called by muse, mutect2, varscan2
- FOXD4L4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 68/1494 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1436721691; called by muse, mutect2
- FOXD4L5 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 74/788 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs775962323; called by muse, mutect2
- IGBP1P2 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53619834; called by muse, mutect2, varscan2
- LCORL | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs1196991321; called by muse, varscan2
- LUM | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396589178, COSV99899087; called by muse, mutect2, varscan2
- MMRN1 | c.1336G>T p.V446L | Missense Mutation (SNP) | VAF 134/293 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs942928493; called by muse, mutect2, varscan2
- MRPS31 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV60266636; called by muse, mutect2, varscan2
- NRCAM | c.1669G>A p.V557M (on ENST00000379028 / NM_001371124.1; = p.V551M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs775847052; called by muse, mutect2, varscan2
- RYR3 | c.2731C>T p.L911F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1180930909; called by muse, mutect2, varscan2
- SEC24B | c.2305A>T p.I769L | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV54497574; called by muse, mutect2, varscan2
- ST18 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 171/400 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99390507; called by muse, mutect2, varscan2
- TAF4B | c.482C>A p.T161K | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV52301475; called by muse, mutect2
- TG | c.6238G>T p.V2080F | Missense Mutation (SNP) | VAF 142/527 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV99599004; called by muse, mutect2, varscan2
- ACAN | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ANKRD12 | c.6057G>C p.Q2019H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATF6 | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- C2orf16 | c.3676G>T p.A1226S | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CD163L1 | c.3410-19_3411del p.X1137_splice | Splice Site (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel
- CELSR3 | c.3710A>T p.N1237I | Missense Mutation (SNP) | VAF 162/241 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CSPP1 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DCTPP1 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.22); called by muse, mutect2
- DDX43 | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- DHX8 | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2
- DNAH3 | c.9460T>A p.Y3154N | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1809C>G p.F603L | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM174A | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, varscan2
- GOLGA8S | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- GPR37 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IZUMO3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- KIF1A | c.2073_2084del p.E691_E694del | In Frame Del (DEL) | VAF 45/69 reads (65%) | called by mutect2, pindel, varscan2
- MARVELD1 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- MFF | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 122/500 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MRC1 | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 105/464 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MUC5AC | c.16904C>T p.P5635L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYO15A | c.9638T>A p.L3213H | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOCD | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NANOGNB | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 132/491 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NBPF15 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NCKAP1L | c.2281G>C p.D761H | Missense Mutation (SNP) | VAF 20/451 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEFM | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 105/192 reads (55%) | called by muse, mutect2, varscan2
- NLRP5 | c.2133G>T p.W711C | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- OR10H5 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.369); called by mutect2, varscan2
- PTPN13 | c.2119C>A p.L707I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RALGPS2 | c.1040+7A>C | Splice Region (SNP) | VAF 37/174 reads (21%) | called by muse, mutect2, varscan2
- RGS6 | c.1092-2A>T p.X364_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- RTN3 | c.2399G>A p.G800E (on ENST00000377819 / NM_001265589.2; = p.G781E on NM_201428.3) | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR2 | c.3196G>T p.A1066S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SCAF4 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEC24B | c.3290A>G p.D1097G | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC17A8 | c.777T>G p.I259M | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- TNR | c.1144A>C p.I382L | Missense Mutation (SNP) | VAF 93/516 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TOR4A | c.700C>A p.R234S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, varscan2
- UHRF1BP1L | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2
- WSCD2 | c.1443_1457del p.E481_Q485del | In Frame Del (DEL) | VAF 102/348 reads (29%) | called by mutect2, pindel, varscan2
- ZC3HAV1 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSWIM5 | c.2156-1G>A p.X719_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- ADAD2 | c.1176C>A p.G392= (on ENST00000315906 / NM_001145400.2; = p.G474= on NM_139174.4) | Silent (SNP) | VAF 3/56 reads (5%) | called by muse, mutect2
- ARHGAP9 | c.1956C>A p.P652= (on ENST00000393797 / NM_001319850.2; = p.P633= on NM_032496.4) | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- DRAM1 | c.171A>G p.G57= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV51598424; called by muse, mutect2
- EPHA7 | c.2427G>A p.Q809= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV65191896; called by muse, mutect2, varscan2
- MOGAT3 | c.642C>G p.G214= | Silent (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- MYH4 | c.2130G>A p.R710= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV55128007; called by muse, mutect2, varscan2
- NALCN | c.1305G>C p.L435= | Silent (SNP) | VAF 143/254 reads (56%) | called by muse, mutect2, varscan2
- OR4K15 | c.996T>A p.P332= (on ENST00000305051; = p.P308= on NM_001005486.1) | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- PRRT4 | c.591G>T p.L197= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- PTHLH | c.486G>C p.L162= | Silent (SNP) | VAF 84/346 reads (24%) | called by muse, mutect2, varscan2
- ALG3 | chr3:184249004 T>C | 5'Flank (SNP) | VAF 386/411 reads (94%) | called by muse, mutect2, varscan2
- APOC3 | c.*8A>G | 3'UTR (SNP) | VAF 160/572 reads (28%) | catalogued as rs548741530; called by muse, mutect2, varscan2
- COLEC11 | c.-75C>A | 5'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs1353445065; called by muse, mutect2
- COLEC11 | c.203-11485C>G | Intron (SNP) | VAF 44/897 reads (5%) | catalogued as COSV52593909, COSV52594800; called by muse, mutect2
- DCUN1D5 | c.*16G>C | 3'UTR (SNP) | VAF 11/226 reads (5%) | called by muse, mutect2
- DNAJC4 | c.-81C>T | 5'UTR (SNP) | VAF 18/54 reads (33%) | catalogued as rs971687677; called by muse, varscan2
- FOXP2 | c.*2386A>T | 3'UTR (SNP) | VAF 81/368 reads (22%) | called by muse, mutect2, varscan2
- MDFI | c.-11-37G>T | Intron (SNP) | VAF 178/259 reads (69%) | called by muse, mutect2, varscan2
- MMD | c.-12A>G | 5'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- NTPCR | c.-91C>T | 5'UTR (SNP) | VAF 28/211 reads (13%) | called by muse, mutect2, varscan2
- PFKFB4 | chr3:48561130 G>A | 5'Flank (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- PPP4R1L | n.2087+940A>C | Intron (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- RHBDF1 | c.249-157C>T | Intron (SNP) | VAF 35/124 reads (28%) | called by muse, mutect2
- SMIM29 | c.*46_*51del | 3'UTR (DEL) | VAF 45/171 reads (26%) | called by mutect2, pindel, varscan2
- ZNF141 | c.-70C>G | 5'UTR (SNP) | VAF 60/106 reads (57%) | called by muse, mutect2, varscan2
